Gene-level copy-number profile of tumor specimen TCGA-DX-AB2O-01A from TCGA case TCGA-DX-AB2O, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.7 years (28,757 days).
Specimen TCGA-DX-AB2O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.d5407aa9-65ec-40e1-8d00-2957ce7fb345.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-AB2O-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7071d08f-673a-4aef-b11c-ad6c1c748261

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 3,630; copy number 2: 12,142; copy number 3: 25,185; copy number 4: 12,759; copy number 5: 4,401; copy number 6: 1,189; copy number 7: 386; copy number 8: 18; copy number 9: 23; copy number 10: 3; copy number 20: 9; copy number 37: 10; copy number 38: 2; copy number 46: 12; copy number 49: 4; copy number 52: 2; copy number 59: 3; copy number 67: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-AB2O-01A-12D-A38Y-01): tumor purity 0.93, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,134,358–49,495,003, 29 genes: POLR2KP2, ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 480 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:18,839,599–21,345,572, 71 genes, copy number 7 (broad region; genes not listed).
- chr1:38,383,838–42,844,991, 135 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:58,776,845–60,868,009, 22 genes, copy number 37–46 (within-gene range 5–46): JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1.
- chr1:246,025,897–246,113,866, 2 genes, copy number 7: AC118555.1, SMYD3-AS1.
- chr2:127,931,327–128,028,120, 2 genes, copy number 38 (within-gene range 3–38): AC012306.1, SAP130.
- chr2:139,732,708–140,221,485, 7 genes, copy number 7: RPL9P13, AC078851.1, RN7SL283P, LINC01853, MTCO1P44, MTND2P19, MTND1P27.
- chr2:140,234,737–140,234,923, 1 gene, copy number 7: AC092156.1.
- chr2:179,273,831–179,861,612, 5 genes, copy number 52–59: AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258.
- chr2:184,378,975–184,379,044, 1 gene, copy number 8: MIR548AE1.
- chr2:187,001,876–187,556,288, 4 genes, copy number 9 (within-gene range 3–9): IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P.
- chr2:193,256,483–193,277,614, 2 genes, copy number 10: SLC44A3P1, DNAJC17P1.
- chr3:84,958,989–87,276,584, 17 genes, copy number 20–67 (within-gene range 3–79): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1.
- chr4:3,041,422–3,763,390, 18 genes, copy number 7: HTT, RNU6-204P, HTT-AS, AL390065.2, AL390065.1, MSANTD1, RGS12, AL645949.1, AL645949.2, HGFAC, AL590235.2, DOK7, LRPAP1, AL590235.1, LINC00955, AL121796.1, LINC02171, LINC02600.
- chr4:6,909,242–7,068,064, 8 genes, copy number 8 (within-gene range 2–8): TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1.
- chr4:36,426,366–36,641,939, 3 genes, copy number 7: MIR1255B1, LINC02505, AC125336.1.
- chr4:39,399,149–39,782,792, 19 genes, copy number 9: RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3, RNU7-11P, AC108471.2, UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP.
- chr4:42,397,488–42,402,487, 1 gene, copy number 7: SHISA3.
- chr4:64,275,257–65,024,485, 13 genes, copy number 7 (within-gene range 2–7): TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, AC104689.2, LINC02232.
- chr4:76,401,251–76,802,426, 9 genes, copy number 8: AC096743.2, AC096743.1, SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1.
- chr8:15,688,914–16,915,044, 10 genes, copy number 7 (within-gene range 6–13): AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1.
- chr8:17,224,966–17,246,878, 1 gene, copy number 10: CNOT7.
- chr8:27,886,039–27,910,310, 4 genes, copy number 7: MIR4287, AC069113.1, AC069113.3, AC069113.2.
- chr8:30,176,554–31,390,805, 30 genes, copy number 7: AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG, WRN, SUMO2P16, AC009563.1, KCTD9P6, AC068672.2, AC068672.3.
- chr13:113,491,021–114,337,626, 29 genes, copy number 7 (within-gene range 5–7): TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, GRK1, LINC00552, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46, RASA3, RASA3-IT1, CFAP97D2, AL160396.1, CDC16, MIR548AR, MIR4502, AL160396.2, UPF3A, CLCP2, CHAMP1, LINC01054.
- chr14:87,251,103–87,573,022, 4 genes, copy number 49: AL352955.1, AL157688.1, LINC02296, AL135746.1.
- chr14:102,777,449–103,858,049, 50 genes, copy number 7 (within-gene range 6–7): TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5, MARK3, RPL10AP1, CKB, AL133367.1, TRMT61A, RNU7-160P, AL139300.2, BAG5, KLC1, COA8, AL139300.1, RNU4-68P, AL049840.2, AL049840.6, AL049840.3, AL049840.4, AL049840.5, XRCC3, ZFYVE21, Y_RNA, PPP1R13B, AL049840.7, AL049840.1, LINC00637.
- chr17:11,288,205–11,290,811, 1 gene, copy number 7: AC005725.1.
- chr17:14,705,076–14,780,686, 3 genes, copy number 7: RPS18P12, AC013248.1, AC005863.1.
- chr17:19,737,682–19,897,287, 8 genes, copy number 7: AC005722.4, ALDH3A1, AC005722.1, ULK2, NDUFB4P3, AC015726.3, AC015726.2, AC015726.1.

Autosomal genes at a single copy (total copy number 1): 2,625. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
